Somatic mutation profile of cancer-model specimen HCM-CSHL-0725-C02-85A (3D Organoid, passage 7; aliquot HCM-CSHL-0725-C02-85A-01D-A85K-36), derived from the primary tumor of HCMI case HCM-CSHL-0725-C02, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS.
Specimen HCM-CSHL-0725-C02-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3eb18da3-f700-4b2a-8adc-ad67e7afc1f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0725-C02-11A (Solid Tissue Normal), aliquot HCM-CSHL-0725-C02-11A-11D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db08a417-3399-42d6-8511-614fdd3d4d69

The open-access MAF lists 78 somatic variants for this specimen: 49 protein-altering or splice-affecting, 23 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 23, Nonsense Mutation 5, Frame Shift Del 5, Intron 2, RNA 2, Splice Site 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 184/357 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1057520005, COSV52707923, COSV52708386, COSV52728497, COSV53727597; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AJM1 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 284/575 reads (49%) | catalogued as rs1222994872; called by muse, mutect2, varscan2
- ARID2 | c.4039C>T p.Q1347* | Nonsense Mutation (SNP) | VAF 146/404 reads (36%) | catalogued as rs1170525254, COSV57605170, COSV57608980; called by muse, mutect2, varscan2
- BRI3BP | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 187/577 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as rs1458881001, COSV58296294; called by muse, mutect2, varscan2
- C4BPA | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs867500835, CM132732, COSV65536149; called by muse, mutect2, varscan2
- DHX58 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 175/343 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1285692904, COSV52424984; called by muse, mutect2, varscan2
- DIPK2B | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 251/477 reads (53%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.014); catalogued as rs199728771; called by muse, mutect2, varscan2
- DNAH7 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 149/294 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs780057760, COSV56758361; called by muse, mutect2, varscan2
- DNAJC28 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 210/422 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761112395; called by muse, mutect2, varscan2
- DUSP16 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 98/200 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV53808862; called by muse, mutect2, varscan2
- EPHB1 | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 195/404 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as rs534330476, COSV67653771, COSV67669910; called by muse, mutect2, varscan2
- EXOC8 | c.1952T>C p.I651T | Missense Mutation (SNP) | VAF 133/297 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs146418424; called by muse, mutect2, varscan2
- FMN2 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 271/577 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as COSV60452833; called by muse, mutect2, varscan2
- FNDC11 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 367/592 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs757814732, COSV64442542; called by muse, mutect2, varscan2
- FREM1 | c.3205C>G p.Q1069E | Missense Mutation (SNP) | VAF 161/313 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV66525188; called by muse, mutect2, varscan2
- LRRC61 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 181/388 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs142041407, COSV56232024; called by muse, mutect2, varscan2
- MACF1 | c.20735G>A p.R6912Q (on ENST00000372915; = p.R4957Q on NM_012090.5) | Missense Mutation (SNP) | VAF 110/249 reads (44%) | catalogued as rs756134944, COSV57103765; called by muse, mutect2, varscan2
- MAGEC3 | c.1079G>C p.R360P | Missense Mutation (SNP) | VAF 139/255 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV53575583; called by muse, mutect2, varscan2
- MAP1A | c.5216A>T p.E1739V | Missense Mutation (SNP) | VAF 196/402 reads (49%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.101); catalogued as rs768732133; called by muse, mutect2, varscan2
- MATN1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 158/332 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs781008601, COSV65650612; called by muse, varscan2
- MYO3A | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 76/168 reads (45%) | catalogued as COSV56349554; called by muse, varscan2
- PFDN5 | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 141/248 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54476932; called by muse, mutect2, varscan2
- PIWIL3 | c.2141C>T p.S714L | Missense Mutation (SNP) | VAF 114/276 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.34); catalogued as rs762679294; called by muse, mutect2, varscan2
- TMEM131 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 103/332 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs773610584, COSV99488836; called by muse, mutect2, varscan2
- TSR2 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 94/203 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs376978451, COSV64309380; called by muse, mutect2, varscan2
- ZFP36L2 | c.968_990del p.A323Gfs*143 | Frame Shift Del (DEL) | VAF 210/683 reads (31%) | catalogued as rs1334690264; called by mutect2, pindel, varscan2
- ACAN | c.5210del p.G1737Dfs*16 | Frame Shift Del (DEL) | VAF 176/422 reads (42%) | called by mutect2, pindel, varscan2
- AJUBA | c.657del p.A220Rfs*22 | Frame Shift Del (DEL) | VAF 220/602 reads (37%) | called by pindel, varscan2
- AJUBA | c.557_575del p.P186Rfs*50 | Frame Shift Del (DEL) | VAF 196/464 reads (42%) | called by pindel, varscan2
- AL592490.1 | c.1891G>T p.D631Y | Missense Mutation (SNP) | VAF 171/338 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATAD5 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 127/282 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- CBWD2 | c.908T>A p.V303E | Missense Mutation (SNP) | VAF 116/391 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- CCM2L | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 404/655 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- CPB2 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- FBXO33 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FRMD4B | c.3071G>T p.W1024L | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GABRA2 | c.1234A>C p.N412H | Missense Mutation (SNP) | VAF 189/379 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNA13 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1-8 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 206/344 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LRRK1 | c.5562G>C p.R1854S | Missense Mutation (SNP) | VAF 230/459 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K19 | c.706A>T p.R236* | Nonsense Mutation (SNP) | VAF 154/307 reads (50%) | called by muse, mutect2, varscan2
- NBPF10 | c.10765del p.Y3589Mfs*67 | Frame Shift Del (DEL) | VAF 133/511 reads (26%) | called by mutect2, pindel, varscan2
- NID2 | c.1072T>A p.S358T | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PANK2 | c.295T>C p.W99R | Missense Mutation (SNP) | VAF 204/607 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PVR | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 149/290 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- STT3A | c.1394C>A p.A465D | Missense Mutation (SNP) | VAF 97/213 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- TNFRSF8 | c.1416C>A p.C472* | Nonsense Mutation (SNP) | VAF 21/456 reads (5%) | called by muse, mutect2
- ZNF638 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 242/345 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNHIT6 | c.1089-7_1110delinsAC p.X363_splice | Splice Site (DEL) | VAF 37/105 reads (35%) | called by pindel, varscan2*
- ADRA2A | c.810C>T p.P270= | Silent (SNP) | VAF 178/358 reads (50%) | called by muse, mutect2, varscan2
- APAF1 | c.3118C>T p.L1040= (on ENST00000551964 / NM_181861.2; = p.L986= on NM_001160.3) | Silent (SNP) | VAF 107/293 reads (37%) | called by muse, mutect2, varscan2
- APBB2 | c.315C>T p.N105= | Silent (SNP) | VAF 186/399 reads (47%) | called by muse, mutect2, varscan2
- ARID3B | c.1317G>A p.S439= | Silent (SNP) | VAF 210/442 reads (48%) | catalogued as rs768356045, COSV60558097; called by muse, mutect2, varscan2
- C15orf39 | c.2022T>A p.A674= | Silent (SNP) | VAF 256/502 reads (51%) | called by muse, mutect2, varscan2
- CCNJL | c.432C>T p.F144= | Silent (SNP) | VAF 97/216 reads (45%) | catalogued as rs756671371, COSV57444316, COSV99979293; called by muse, mutect2, varscan2
- CFAP46 | c.6021C>T p.S2007= | Silent (SNP) | VAF 270/516 reads (52%) | called by muse, mutect2, varscan2
- CFAP65 | c.2301C>T p.F767= | Silent (SNP) | VAF 168/355 reads (47%) | catalogued as rs758153611, COSV58564031; called by muse, mutect2, varscan2
- CHAD | c.114C>T p.C38= | Silent (SNP) | VAF 188/361 reads (52%) | called by muse, mutect2, varscan2
- EFCAB8 | c.2310A>G p.S770= | Silent (SNP) | VAF 129/400 reads (32%) | called by muse, mutect2, varscan2
- GRIA4 | c.2697G>A p.S899= | Silent (SNP) | VAF 109/234 reads (47%) | catalogued as rs770881664, COSV56914255; called by muse, mutect2, varscan2
- GTPBP3 | c.219T>A p.L73= | Silent (SNP) | VAF 218/433 reads (50%) | called by mutect2, varscan2
- HTATSF1 | c.1575C>G p.L525= | Silent (SNP) | VAF 93/202 reads (46%) | called by muse, mutect2, varscan2
- PCSK1N | c.387C>T p.P129= | Silent (SNP) | VAF 336/708 reads (47%) | catalogued as rs922794082; called by muse, mutect2
- PGA3 | c.444C>T p.Y148= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1490406913; called by mutect2, varscan2
- PHEX | c.2094A>T p.P698= | Silent (SNP) | VAF 171/347 reads (49%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.1758C>T p.Y586= | Silent (SNP) | VAF 176/357 reads (49%) | catalogued as rs150213699; called by muse, mutect2, varscan2
- SLC47A1 | c.1269C>T p.I423= | Silent (SNP) | VAF 144/316 reads (46%) | catalogued as rs774900748, COSV99565586; called by muse, mutect2, varscan2
- SNX8 | c.1180C>T p.L394= | Silent (SNP) | VAF 177/391 reads (45%) | catalogued as rs1417670788, COSV56128749; called by muse, mutect2, varscan2
- TDRD6 | c.2934T>C p.S978= | Silent (SNP) | VAF 143/279 reads (51%) | called by muse, mutect2, varscan2
- TMC8 | c.1945C>T p.L649= | Silent (SNP) | VAF 204/394 reads (52%) | called by muse, mutect2, varscan2
- UGT2B28 | c.297C>T p.D99= | Silent (SNP) | VAF 73/215 reads (34%) | catalogued as rs942284808; called by muse, mutect2, varscan2
- ZNF697 | c.936G>A p.T312= | Silent (SNP) | VAF 246/508 reads (48%) | catalogued as rs750755044; called by muse, mutect2, varscan2
- AC092070.2 | n.433A>T | RNA (SNP) | VAF 161/321 reads (50%) | called by muse, mutect2, varscan2
- INPP4B | c.2643-1311G>A | Intron (SNP) | VAF 133/310 reads (43%) | catalogued as rs1042552156; called by muse, mutect2, varscan2
- KIR3DX1 | n.630C>A | RNA (SNP) | VAF 115/266 reads (43%) | catalogued as COSV55596608; called by muse, mutect2, varscan2
- PDLIM5 | c.921-7796G>A | Intron (SNP) | VAF 119/266 reads (45%) | catalogued as rs750105003; called by muse, mutect2, varscan2
- RPGR | c.-90G>A | 5'UTR (SNP) | VAF 200/406 reads (49%) | called by muse, mutect2, varscan2
- TRIM10 | c.*206C>A | 3'UTR (SNP) | VAF 196/409 reads (48%) | called by muse, mutect2, varscan2
